Somatic mutation profile of tumor specimen TCGA-BP-5010-01A (aliquot TCGA-BP-5010-01A-02D-1421-08) from TCGA case TCGA-BP-5010, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 63.3 years (23,130 days).
Specimen TCGA-BP-5010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5509bfc-1b7f-468a-bcb5-048806ed65de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5010-11A (Solid Tissue Normal), aliquot TCGA-BP-5010-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79b303e3-c575-49aa-bc57-bc2c7767759d

The open-access MAF lists 71 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Frame Shift Del 10, Frame Shift Ins 4, Nonsense Mutation 2, Intron 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAG2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 76/219 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54357904; called by muse, mutect2, varscan2
- AP002748.5 | c.1085A>C p.Q362P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59148529; called by muse, mutect2, varscan2
- AQR | c.1875T>A p.F625L | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV50033711; called by muse, mutect2, varscan2
- CD180 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV56517947; called by muse, mutect2, varscan2
- CD300LG | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs373847576, COSV53223742; called by muse, mutect2, varscan2
- CDCA2 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57945749; called by muse, mutect2, varscan2
- CPNE7 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52012705; called by muse, mutect2, varscan2
- DENND2C | c.1771T>G p.Y591D (on ENST00000393274 / NM_001256404.2; = p.Y534D on NM_198459.4) | Missense Mutation (SNP) | VAF 81/455 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV67921629; called by muse, mutect2, varscan2
- DSCAM | c.4578G>T p.R1526S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs1568929146, COSV68026244; called by muse, mutect2, varscan2
- FAM107B | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51683948; called by muse, mutect2, varscan2
- GPLD1 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV57756860; called by muse, mutect2
- HNRNPM | c.374T>A p.M125K | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57692575; called by muse, mutect2, varscan2
- KDR | c.3322G>T p.G1108W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55764524; called by muse, mutect2, varscan2
- KIAA0930 | c.75G>C p.K25N (on ENST00000336156 / NM_001009880.2; = p.K30N on NM_015264.2) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV52663155; called by muse, mutect2, varscan2
- KLF3 | c.1015A>G p.R339G | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV54710674; called by muse, mutect2, varscan2
- MAS1 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.163); catalogued as COSV53121192; called by muse, mutect2, varscan2
- MEF2D | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs1158562298, COSV61728156; called by muse, mutect2, varscan2
- MICAL1 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62193389; called by muse, mutect2, varscan2
- MYO18B | c.6548A>G p.H2183R | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59133721; called by muse, mutect2, varscan2
- N6AMT1 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs761729543, COSV58134310, COSV58134349; called by muse, mutect2, varscan2
- NUP205 | c.3221C>T p.S1074F | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV53658762; called by muse, mutect2, varscan2
- OAZ3 | c.394T>G p.S132A | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as COSV100162382, COSV58618159; called by muse, mutect2, varscan2
- PAH | c.134T>A p.V45D | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as CM123673, COSV61016282; called by muse, mutect2, varscan2
- PCMTD1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62119200; called by muse, mutect2, varscan2
- PFN4 | c.371T>A p.L124Q | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1451011077, COSV57531311; called by muse, mutect2, varscan2
- PTCHD4 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.592); catalogued as COSV59783564; called by muse, mutect2, varscan2
- RASGRF2 | c.3356C>A p.T1119K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV54129331; called by muse, mutect2, varscan2
- RUVBL2 | c.1002-1G>A p.X334_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV55485101; called by muse, mutect2, varscan2
- SALL4 | c.2222T>C p.F741S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs974783661, COSV53852020, COSV99409431; called by muse, mutect2, varscan2
- SCNN1G | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV55598723; called by muse, mutect2, varscan2
- SIPA1L2 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53390003; called by muse, mutect2
- SNX33 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774524839, COSV57913415; called by muse, mutect2, varscan2
- STRN3 | c.914T>A p.F305Y | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV62579493; called by muse, mutect2, varscan2
- TARS3 | c.463A>T p.K155* | Nonsense Mutation (SNP) | VAF 51/288 reads (18%) | catalogued as COSV60108037; called by muse, mutect2, varscan2
- TMEM132D | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV70603868; called by muse, mutect2, varscan2
- TTBK1 | c.3570C>A p.S1190R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV52491025; called by muse, mutect2
- VHL | c.603dup p.T202Dfs*54 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | catalogued as COSV56569885; called by mutect2, pindel
- XPO1 | c.3149A>G p.H1050R | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756595032, COSV68945903; called by muse, mutect2, varscan2
- ZFX | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); catalogued as COSV58447472; called by muse, mutect2, varscan2
- ZNF415 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV54700941; called by muse, mutect2, varscan2
- ZSCAN20 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63681809, COSV63682565; called by muse, mutect2, varscan2
- CCDC80 | c.1397dup p.N466Kfs*38 | Frame Shift Ins (INS) | VAF 27/117 reads (23%) | called by mutect2, pindel, varscan2
- FAM20B | c.652del p.E218Rfs*43 | Frame Shift Del (DEL) | VAF 23/166 reads (14%) | called by mutect2, pindel, varscan2
- FBXL13 | c.1583del p.N528Tfs*8 | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | called by mutect2, pindel, varscan2
- KRT16 | c.715del p.M239Cfs*6 | Frame Shift Del (DEL) | VAF 16/137 reads (12%) | called by mutect2, pindel, varscan2
- PCDHB11 | c.1106_1108del p.S369del | In Frame Del (DEL) | VAF 42/219 reads (19%) | called by mutect2, pindel, varscan2
- PDE6B | c.1890_1903del p.E631Pfs*50 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- POC5 | c.827_849del p.Y276Cfs*26 (on ENST00000428202 / NM_001099271.2; = p.Y251Cfs*26 on NM_152408.2) | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel
- PTEN | c.588dup p.K197Qfs*5 | Frame Shift Ins (INS) | VAF 49/247 reads (20%) | called by mutect2, pindel, varscan2
- RAD17 | c.815_816del p.F272Sfs*14 (on ENST00000380774 / NM_133339.2; = p.F261Sfs*14 on NM_002873.1) | Frame Shift Del (DEL) | VAF 42/274 reads (15%) | called by mutect2, pindel, varscan2
- SCAF4 | c.558_564del p.F186Lfs*36 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- TCP11L1 | c.949dup p.H317Pfs*53 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- THOC1 | c.938_941del p.S313Tfs*32 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- TTBK2 | c.70-16_81del p.X24_splice | Splice Site (DEL) | VAF 12/138 reads (9%) | called by mutect2, pindel
- TTLL5 | c.3736del p.S1246Pfs*10 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- ZNF22 | c.162del p.Y55Ifs*128 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, pindel, varscan2
- ABCA13 | c.14646G>A p.E4882= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV68946456; called by muse, mutect2, varscan2
- CACNA1H | c.3108C>T p.V1036= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1176643514, COSV61989720; called by muse, mutect2
- CAGE1 | c.1719G>A p.E573= (on ENST00000512086; = p.E437= on NM_205864.3) | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57077214; called by muse, mutect2, varscan2
- CNOT10 | c.399T>A p.G133= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs1485655543, COSV59391944; called by muse, mutect2, varscan2
- COX7A2 | c.321G>A p.V107= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV57873905; called by muse, mutect2, varscan2
- CREB3 | c.681C>T p.S227= | Silent (SNP) | VAF 52/189 reads (28%) | catalogued as COSV59207282; called by muse, mutect2, varscan2
- CYP39A1 | c.1062T>A p.I354= | Silent (SNP) | VAF 44/220 reads (20%) | catalogued as COSV51495459; called by muse, mutect2, varscan2
- EIF4G3 | c.1885C>T p.L629= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as COSV51681445; called by muse, mutect2, varscan2
- INVS | c.723C>T p.T241= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV52441696; called by muse, mutect2, varscan2
- PDILT | c.1077C>A p.L359= | Silent (SNP) | VAF 51/280 reads (18%) | catalogued as COSV56701747, COSV56701789; called by muse, mutect2, varscan2
- RFX6 | c.1296C>T p.S432= | Silent (SNP) | VAF 59/263 reads (22%) | catalogued as COSV60584790; called by muse, mutect2, varscan2
- SCN10A | c.1053C>A p.R351= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV71861253; called by muse, mutect2, varscan2
- SPG11 | c.5025T>A p.S1675= | Silent (SNP) | VAF 38/222 reads (17%) | catalogued as COSV55994714; called by muse, mutect2, varscan2
- GLS | c.1650+1100T>A | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100290484; called by muse, mutect2, varscan2
- SLC16A10 | c.942+762A>C | Intron (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
